Surgical pathology report (de-identified scan), TCGA case TCGA-06-0878, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0878-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

06-0878

CLINICAL HISTORY

[REDACTED] had a spell, possibly a stroke, but lesion has increased in size. On imaging there is an intra axial, enhancing lesion in the left posterior temporal lobe.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain tumor, left temporal, biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, left temporal, excisional biopsy: Glioblastoma.
See Comment.

COMMENT

The specimen is portions of an astrocytic neoplastic proliferation with nuclear anaplasia, brisk mitotic activity, microvascular cellular proliferation, and zones of necrosis, some with pseudopalisading, i.e. a glioblastoma.

Special stains to better characterize the neoplasm have been requested, and results will be reported as an addendum.

PROCEDURES/ADDENDA

Immunohistology

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

Brain, MIB-1 proliferation index: 13%

See Results and Comment (below).

Results-Comments

[page 2 of 3]
IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a gliofibrillary background within the tumor. Less than 100 cells over express the p53 protein. The CD163 highlights cells around areas of necrosis. With the MIB-1 there is a proliferation index of about 13% throughout the neoplasm.

Comment: The immunoresults support the diagnosis of glioblastoma.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Test performed on paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

INTRA-OPERATIVE CONSULTATION

A.

Brain tumor, left temporal, biopsy, touch prep and smears: Glioma (C/W high histological grade). [REDACTED] Touch preparation smears performed at [REDACTED] Hospital and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A.

Received fresh, one fragment, 0.9 cm. Across. Semi firm, grayish-blue, focally hemorrhagic, glistening. In total, A1 and A2.

ICD-9(s):

239.6 239.6

[page 3 of 3]
Histo Data

Part A: Brain tumor, left temporal, biopsy

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
CD163 Vector x 1	1	[REDACTED]	
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MGMT x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
P53DO7 x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 745006ef-8fb6-44d5-8e4e-cb28c46efda7 (TCGA-06-0878.31037A8E-696A-4858-90CA-84578F350B7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).